Surgical pathology report (de-identified scan), TCGA case TCGA-BR-6566, project TCGA-STAD (Stomach Adenocarcinoma), tissue source site Asterand, specimen TCGA-BR-6566-01A (Primary Tumor).

[page 1 of 2]
Formatted Path Report		
		STOMACH TISSUE CHECKLIST Specimen type: Gastric resection Tumor site: Stomach Tumor size: 11 x 9 x 2 cm Tumor features: Ulcerated Histologic type: Adenocarcinoma Histologic grade: Poorly differentiated Tumor extent: Adjacent structures (specify) - greater omentum Lymph nodes: 0/3 positive for metastasis (0/3) Lymphatic invasion: Not specified Venous invasion: Not specified Perineural invasion: Not specified Margins: Not specified Evidence of neo-adjuvant treatment: Not specified Additional pathologic findings: Not specified Comments: None

[page 2 of 2]
Date of Procurement

[illegible]

Source: NCI Genomic Data Commons file 156eec25-4f14-4fee-bfbd-a57565e115e0 (TCGA-BR-6566.83393448-21ED-40C8-9463-44F4F2389E54.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).